Somatic mutation profile of tumor specimen ALCH-B1MB-TTP1-A (aliquot ALCH-B1MB-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1MB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,357 days).
Specimen ALCH-B1MB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2949b2de-d55f-4039-9a9e-faf180aa50cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MB-NB1-A (Blood Derived Normal), aliquot ALCH-B1MB-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65142aaa-2243-4622-ac1f-f470ec1ef60d

The open-access MAF lists 328 somatic variants for this specimen: 226 protein-altering or splice-affecting, 73 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 73, Nonsense Mutation 19, Intron 8, 3'UTR 7, RNA 5, Splice Site 5, 5'UTR 4, 5'Flank 4, Splice Region 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 110/533 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13339G>T p.D4447Y | Missense Mutation (SNP) | VAF 44/381 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68950146; called by muse, mutect2, varscan2
- AMPD1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 66/817 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV62415423; called by muse, mutect2
- AMPD1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 66/819 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV62415523; called by muse, mutect2
- ANK3 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1444801503, COSV55058142; called by muse, mutect2
- APC | c.4393A>G p.S1465G | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as CD920821, COSV57393327; called by muse, mutect2
- APOB | c.4502A>G p.Y1501C | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs1558565701, COSV51921547; ClinVar: uncertain significance; called by muse, mutect2
- ARHGEF5 | c.4751G>T p.R1584L | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50208015; called by muse, mutect2, varscan2
- ASPA | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 30/622 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as rs139053885; called by muse, mutect2
- ASTN1 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV62507155; called by muse, mutect2
- CD86 | c.934C>A p.R312S (on ENST00000330540 / NM_175862.5; = p.R306S on NM_006889.4) | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs201148004; called by muse, mutect2
- CENPJ | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765885787; called by muse, mutect2
- COL20A1 | c.2246T>A p.L749Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58928702; called by muse, mutect2, varscan2
- COL5A3 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53412909; called by muse, mutect2
- CSMD3 | c.8222C>T p.P2741L | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV52159975; called by muse, mutect2
- DENND2A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs766779073, COSV52050018; called by muse, mutect2, varscan2
- EHMT2 | c.2167A>T p.M723L | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs1414911977; called by muse, mutect2, varscan2
- ENOX1 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 26/283 reads (9%) | catalogued as COSV54902571; called by muse, mutect2
- EYS | c.2128C>G p.P710A | Missense Mutation (SNP) | VAF 46/555 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.52); catalogued as rs1372870016; called by muse, mutect2
- FLG | c.1759C>A p.R587S | Missense Mutation (SNP) | VAF 63/481 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.942); catalogued as COSV64247081; called by muse, mutect2, varscan2
- GBP6 | c.341G>T p.W114L | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65012268; called by muse, mutect2, varscan2
- GJC2 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs759236425, CD041916; called by muse, mutect2
- GRM7 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as rs985124222, COSV63130800; called by muse, mutect2
- GTPBP10 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1385541908, COSV55988480, COSV99745879; called by muse, mutect2, varscan2
- ITPR3 | c.3611A>G p.K1204R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as rs1302055055; called by muse, mutect2
- JHY | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57081329; called by muse, mutect2
- JHY | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57081341; called by muse, mutect2
- KIAA1755 | c.2519G>T p.R840L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as rs186587769, COSV54075059; called by muse, mutect2, varscan2
- LCMT2 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1323484087; called by muse, mutect2, varscan2
- LIPH | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.071); catalogued as COSV99956012; called by muse, mutect2
- LPO | c.1509G>T p.M503I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99228638; called by mutect2, varscan2
- MAP3K1 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 32/604 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68127747; called by muse, mutect2
- MEOX2 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as COSV100011940; called by muse, mutect2, varscan2
- MMP16 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as COSV54154656; called by muse, mutect2
- NOD1 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768166122; called by mutect2, varscan2
- OPRK1 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55574632; called by muse, mutect2
- OPRL1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs1291862461, COSV61092140; called by muse, mutect2, varscan2
- OR11L1 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 39/285 reads (14%) | catalogued as COSV63313987; called by muse, mutect2, varscan2
- OR2L3 | c.349A>C p.M117L | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV63455214; called by muse, mutect2
- OR5W2 | c.928T>C p.F310L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV60614417; called by muse, mutect2
- OR8H2 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1410029273; called by muse, mutect2, varscan2
- PEX2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63813134, COSV63814069; called by muse, mutect2, varscan2
- PEX5L | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs746551798, COSV55838512, COSV55857769; called by muse, mutect2
- PGPEP1L | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1292315334; called by muse, mutect2, varscan2
- PKHD1 | c.4673G>C p.G1558A | Missense Mutation (SNP) | VAF 54/780 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100584626; called by muse, mutect2
- PPARG | c.1230C>A p.S410R (on ENST00000287820 / NM_015869.5; = p.S380R on NM_005037.7) | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs148844673, COSV55143139; called by muse, mutect2
- RASAL1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV55655052; called by muse, mutect2
- ROR2 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65219453, COSV65222828; called by muse, mutect2
- SCN5A | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs776363986, CM1212293, COSV100348752; called by muse, mutect2, varscan2
- SDK1 | c.2710G>T p.G904* | Nonsense Mutation (SNP) | VAF 20/223 reads (9%) | catalogued as rs773378838; called by muse, mutect2
- SFTPD | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as COSV64853870; called by muse, mutect2, varscan2
- SI | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs367672931; called by muse, mutect2
- SLC13A3 | c.1101G>T p.W367C | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51719605; called by muse, mutect2
- SLC16A12 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs75915990; called by muse, mutect2, varscan2
- SPATA31A3 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 47/575 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as rs1479462260; called by muse, mutect2
- SPEF2 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 28/292 reads (10%) | catalogued as COSV100607623; called by muse, mutect2
- TBC1D17 | c.1505G>T p.R502M | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680877; called by muse, mutect2
- TNFSF9 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs375400132; called by muse, mutect2, varscan2
- TOP2B | c.3995G>T p.R1332L (on ENST00000264331 / NM_001330700.2; = p.R1327L on NM_001068.3) | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as rs767404382; called by muse, varscan2
- TTC17 | c.2035C>T p.L679F | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs745968558; called by muse, mutect2, varscan2
- VWA8 | c.4910C>A p.A1637D | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65001319; called by muse, mutect2
- WDR62 | c.4411G>A p.V1471M | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as rs1167359670; called by muse, mutect2
- WNK1 | c.2065A>G p.T689A | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs779955391; called by muse, mutect2
- ZNF594 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as rs1337495159; called by muse, mutect2
- ZSCAN1 | c.750G>T p.R250S | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as COSV56608399; called by muse, mutect2
- A2ML1 | c.4268T>A p.V1423E | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- ABCE1 | c.843T>A p.Y281* | Nonsense Mutation (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- ACTL6B | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ADAMTS12 | c.3694G>T p.G1232W | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2
- ADAMTS16 | c.2417C>A p.P806H | Missense Mutation (SNP) | VAF 53/545 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- AHCTF1 | c.3617A>C p.H1206P (on ENST00000366508; = p.H1180P on NM_015446.5) | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- AHNAK | c.4535A>T p.K1512M | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AICDA | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- AK9 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- ALOX5 | c.1655C>A p.A552D | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AMER1 | c.2873G>T p.W958L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ANHX | c.638G>T p.R213M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, varscan2
- ANK3 | c.9823C>T p.P3275S | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- ANXA6 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2
- ARHGAP21 | c.1148A>T p.H383L | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- ARHGAP5 | c.2883T>G p.S961R | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ASIC1 | c.1436G>T p.S479I | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- BOD1L1 | c.7431G>T p.E2477D | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.588); called by muse, mutect2
- BTAF1 | c.1154C>T p.T385I | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- C1orf162 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CACNA2D3 | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- CAPS2 | c.717-1G>T p.X239_splice | Splice Site (SNP) | VAF 38/357 reads (11%) | called by muse, mutect2, varscan2
- CD84 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- CDC42BPA | c.4095G>T p.M1365I (on ENST00000334218 / NM_001366019.2; = p.M1352I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CDC6 | c.1673G>C p.G558A | Missense Mutation (SNP) | VAF 57/633 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CDH6 | c.1452C>A p.N484K | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2
- CHL1 | c.3521T>A p.L1174H (on ENST00000397491 / NM_001253387.1; = p.L1190H on NM_006614.4) | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.068); called by muse, mutect2
- CHRNB2 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- CLSTN2 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- COL5A2 | c.2887G>T p.G963C | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.2120G>C p.G707A (on ENST00000520002; = p.G706A on NM_033225.6) | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH2 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- DBH | c.1352A>G p.K451R | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- DCAF4L2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2
- DEPDC5 | c.3190C>T p.Q1064* (on ENST00000400246; = p.Q1133* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 17/277 reads (6%) | called by muse, mutect2
- DGKB | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by muse, mutect2
- DLGAP3 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DSP | c.6883C>T p.Q2295* | Nonsense Mutation (SNP) | VAF 36/562 reads (6%) | called by muse, mutect2
- EPHB6 | c.1287G>T p.R429S | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ESRRG | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- F13A1 | c.1074T>A p.D358E | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2
- FAM205A | c.2237A>G p.Q746R | Missense Mutation (SNP) | VAF 53/701 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2
- FLG | c.4046C>A p.A1349E | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2
- GABRB3 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIPC3 | c.836A>T p.E279V (on ENST00000644946; = p.S275C on NM_133261.3) | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2
- GPATCH1 | c.1480G>C p.G494R | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- GPLD1 | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIK3 | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HJURP | c.1910A>G p.Q637R | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2
- HOOK1 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- HTRA4 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- HTT | c.4028A>T p.Q1343L | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- IFT122 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 42/451 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- IGKV1D-16 | c.61A>T p.R21* | Nonsense Mutation (SNP) | VAF 36/622 reads (6%) | called by muse, mutect2
- IGSF9B | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO5 | c.2687G>T p.S896I | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- ITSN1 | c.3056del p.G1019Efs*3 | Frame Shift Del (DEL) | VAF 38/281 reads (14%) | called by mutect2, pindel, varscan2
- KCNN1 | c.647C>A p.T216K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KCP | c.1067T>G p.L356R (on ENST00000620378; = p.L413R on NM_001366122.1) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KIAA1109 | c.10000C>T p.Q3334* | Nonsense Mutation (SNP) | VAF 36/430 reads (8%) | called by muse, mutect2
- KIF17 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2
- KIF26B | c.1084T>C p.C362R | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- KNTC1 | c.2099G>T p.R700M | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- KRTAP6-1 | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 37/461 reads (8%) | PolyPhen benign (0.013); called by muse, mutect2
- LAMA1 | c.5143C>T p.H1715Y | Missense Mutation (SNP) | VAF 28/519 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.554); called by muse, mutect2
- LCE6A | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2
- LONRF2 | c.1756G>T p.G586W | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- LRRC53 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.398); called by muse, mutect2
- LY9 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2
- MAGIX | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MAN2A1 | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2
- MAP2 | c.5477G>T p.G1826V | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K4 | c.401A>T p.N134I | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.051); called by mutect2, varscan2
- MAPK6 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 17/467 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MMEL1 | c.1185A>G p.I395M | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MROH9 | c.1667A>T p.Q556L | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MTRNR2L1 | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); called by muse, mutect2
- MUC12 | c.2859A>C p.L953F (on ENST00000379442; = p.L810F on NM_001164462.1) | Missense Mutation (SNP) | VAF 66/1269 reads (5%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.598); called by muse, mutect2
- MYCT1 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- MYT1L | c.935A>G p.E312G | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- NCOR1 | c.2880C>G p.Y960* | Nonsense Mutation (SNP) | VAF 40/460 reads (9%) | called by muse, mutect2
- NLRC5 | c.2801+1G>T p.X934_splice | Splice Site (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- NLRP10 | c.1402A>G p.S468G | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- NPR3 | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTRK3 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2
- NWD2 | c.4570T>A p.L1524M | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2
- ODAM | c.489G>C p.R163S | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- OR10A4 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OR10G9 | c.650A>T p.Y217F | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10J1 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR4B1 | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR5W2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- OVCH1 | c.2774G>T p.R925I | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PABPC5 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 34/428 reads (8%) | called by muse, mutect2
- PCDH10 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- PCDHA2 | c.1124C>G p.S375W | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PCNT | c.4936A>G p.R1646G | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- PDE1C | c.243-1G>T p.X81_splice | Splice Site (SNP) | VAF 12/110 reads (11%) | called by muse, varscan2
- PEG3 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHF2 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.5019G>C p.E1673D | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.903); called by muse, mutect2
- PLCZ1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 53/576 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- PLD1 | c.2303A>T p.H768L | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.143); called by muse, mutect2
- PLEK | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- PPP1R3A | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 25/452 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PRPF6 | c.2350G>T p.V784L | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2
- PRUNE2 | c.8485G>T p.D2829Y | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTCHD1 | c.2383G>T p.G795W | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRN | c.2155T>C p.Y719H | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RCSD1 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); called by muse, mutect2
- RDM1 | c.445A>T p.M149L | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- RGPD2 | c.4030G>T p.E1344* | Nonsense Mutation (SNP) | VAF 50/902 reads (6%) | called by muse, mutect2
- RSPH14 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.5269C>T p.L1757F | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RYR2 | c.6433G>T p.G2145* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | called by mutect2, varscan2
- SAMD9 | c.2607G>T p.L869F | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SATL1 | c.975C>A p.S325R (on ENST00000395409; = p.S512R on NM_001012980.2) | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- SCN1B | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2
- SCUBE2 | c.1535-1G>T p.X512_splice | Splice Site (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- SEL1L3 | c.2588G>A p.W863* | Nonsense Mutation (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- SERPINI2 | c.-9G>C | Splice Region (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- SH3PXD2B | c.2136G>C p.R712S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHISA9 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.01); called by muse, mutect2
- SI | c.1322A>T p.Y441F | Missense Mutation (SNP) | VAF 33/519 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A40 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMAD4 | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 44/421 reads (10%) | called by muse, mutect2, varscan2
- SNTG1 | c.1504T>A p.S502T | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SPATA22 | c.473T>G p.L158* | Nonsense Mutation (SNP) | VAF 36/404 reads (9%) | called by muse, mutect2
- SPON1 | c.260C>G p.P87R | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.788); called by muse, mutect2
- SPTAN1 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- STARD8 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.188); called by muse, mutect2
- STON2 | c.2498G>T p.R833I (on ENST00000649389 / NM_001366849.2; = p.R776I on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SVEP1 | c.6112C>A p.L2038I | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYCP1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- TAP1 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); called by muse, mutect2
- TARBP1 | c.2819C>G p.S940C | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2
- TENM2 | c.334G>T p.G112W | Missense Mutation (SNP) | VAF 31/369 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TENM2 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- TENT4A | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2
- TEX26 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 51/527 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2
- TIAM1 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TMEM131L | c.4351G>T p.E1451* | Nonsense Mutation (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- TMEM234 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2
- TRAF6 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- TRPM1 | c.3812G>C p.S1271T | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.313); called by muse, mutect2
- TUBG2 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.912); called by muse, mutect2
- USH2A | c.1117G>T p.V373F | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2
- VPS13A | c.8206A>T p.T2736S | Missense Mutation (SNP) | VAF 39/482 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- VSTM2A | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- XPO6 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- XPO7 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZAN | c.4526A>T p.N1509I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZDBF2 | c.5060C>T p.A1687V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- ZFHX4 | c.1897A>T p.T633S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.716); called by muse, mutect2
- ZFP42 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2
- ZNF292 | c.3416G>C p.G1139A | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.024); called by muse, mutect2
- ZNF398 | c.901C>T p.Q301* (on ENST00000475153 / NM_170686.3; = p.Q130* on NM_020781.4) | Nonsense Mutation (SNP) | VAF 60/384 reads (16%) | called by muse, mutect2, varscan2
- ZNF492 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF600 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF804B | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF830 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ABCB1 | c.2874G>T p.R958= | Silent (SNP) | VAF 49/506 reads (10%) | called by muse, mutect2
- ADCY8 | c.1665G>T p.T555= | Silent (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- ADGRG4 | c.1461C>T p.N487= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- ANGPT4 | c.1395C>G p.V465= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- APC | c.1926G>T p.V642= | Silent (SNP) | VAF 65/694 reads (9%) | called by muse, mutect2
- ASB11 | c.879G>T p.L293= | Silent (SNP) | VAF 30/291 reads (10%) | called by muse, mutect2, varscan2
- ASCL4 | c.63C>A p.P21= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- CACNA1A | c.7347G>A p.A2449= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1337207067; called by muse, mutect2, varscan2
- CADPS2 | c.135G>T p.P45= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- CES1 | c.831C>A p.T277= | Silent (SNP) | VAF 53/1142 reads (5%) | called by muse, mutect2
- COL26A1 | c.405G>T p.R135= (on ENST00000313669 / NM_001278563.3; = p.R133= on NM_133457.4) | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2
- CTNNA2 | c.480G>A p.L160= | Silent (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- CYC1 | c.555T>G p.A185= | Silent (SNP) | VAF 15/266 reads (6%) | called by muse, mutect2
- DCAF4L2 | c.204T>C p.S68= | Silent (SNP) | VAF 42/508 reads (8%) | catalogued as rs772210414; called by muse, mutect2
- DOCK10 | c.5712A>C p.T1904= | Silent (SNP) | VAF 38/384 reads (10%) | called by muse, mutect2
- DYTN | c.1590A>G p.L530= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- FANCF | c.768A>T p.P256= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- GEMIN5 | c.2829G>C p.G943= | Silent (SNP) | VAF 24/279 reads (9%) | called by muse, mutect2
- GJA8 | c.594G>T p.R198= | Silent (SNP) | VAF 35/248 reads (14%) | called by muse, mutect2, varscan2
- GLUD1 | c.1134A>C p.I378= | Silent (SNP) | VAF 53/716 reads (7%) | called by muse, mutect2
- GMNC | c.681G>A p.P227= | Silent (SNP) | VAF 33/399 reads (8%) | catalogued as rs746342909, COSV71249085; called by muse, mutect2
- HTR7 | c.423C>A p.T141= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as COSV99520423; called by muse, mutect2
- IMPA2 | c.375A>T p.R125= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- KIAA1549L | c.2943C>T p.T981= (on ENST00000321505; = p.T1278= on NM_012194.3) | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV55776749; called by muse, mutect2
- KLB | c.897G>T p.T299= | Silent (SNP) | VAF 9/183 reads (5%) | catalogued as COSV57300813; called by muse, mutect2
- KMT2D | c.14940G>A p.K4980= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV56423981; called by muse, mutect2
- LPA | c.129T>A p.T43= | Silent (SNP) | VAF 40/428 reads (9%) | called by muse, mutect2
- LPAR3 | c.948A>G p.P316= | Silent (SNP) | VAF 28/464 reads (6%) | called by muse, mutect2
- LRIT2 | c.1125G>T p.V375= | Silent (SNP) | VAF 19/196 reads (10%) | catalogued as COSV100259454; called by muse, mutect2
- LUC7L3 | c.240C>T p.G80= | Silent (SNP) | VAF 34/449 reads (8%) | called by muse, mutect2
- MAN2C1 | c.471G>T p.G157= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- MED1 | c.579A>G p.K193= | Silent (SNP) | VAF 17/296 reads (6%) | called by muse, mutect2
- MGAT5B | c.1632G>A p.E544= (on ENST00000569840 / NM_001199172.2; = p.E542= on NM_144677.3) | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- MRPL19 | c.294T>C p.D98= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as rs1452768955; called by muse, mutect2
- MSX2 | c.420G>A p.K140= | Silent (SNP) | VAF 21/269 reads (8%) | catalogued as rs1377517763; called by muse, mutect2
- MUC16 | c.27270A>T p.S9090= | Silent (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.3012A>T p.P1004= | Silent (SNP) | VAF 24/300 reads (8%) | called by muse, mutect2
- NLRP10 | c.1401C>A p.I467= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- NLRP13 | c.252G>T p.V84= | Silent (SNP) | VAF 37/497 reads (7%) | catalogued as rs1011969073, COSV61624356; called by muse, mutect2
- NUCB1 | c.735C>G p.P245= | Silent (SNP) | VAF 9/177 reads (5%) | catalogued as COSV54388173; called by muse, mutect2
- OR13A1 | c.588C>T p.F196= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- OR5AK2 | c.678G>A p.L226= | Silent (SNP) | VAF 11/229 reads (5%) | catalogued as rs990394541, COSV58805020; called by muse, mutect2
- OR5T2 | c.816G>A p.G272= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- PCDHA1 | c.180G>T p.V60= | Silent (SNP) | VAF 33/325 reads (10%) | catalogued as rs782789869; called by muse, mutect2
- PGAP3 | c.57C>T p.S19= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1190415940; called by muse, mutect2
- PIKFYVE | c.552G>T p.G184= | Silent (SNP) | VAF 21/205 reads (10%) | called by muse, mutect2, varscan2
- PLA2G4F | c.57G>A p.G19= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- PLEKHA3 | c.573G>T p.P191= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- POTEI | c.2355C>A p.I785= | Silent (SNP) | VAF 38/596 reads (6%) | called by muse, mutect2
- PRAMEF20 | c.669G>A p.E223= | Silent (SNP) | VAF 60/676 reads (9%) | called by muse, mutect2
- PRR14L | c.5640G>C p.S1880= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV100392248; called by muse, mutect2
- RANBP17 | c.2706C>T p.F902= | Silent (SNP) | VAF 42/467 reads (9%) | called by muse, mutect2
- RBM14 | c.1224C>T p.A408= | Silent (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- RET | c.2905C>A p.R969= | Silent (SNP) | VAF 37/495 reads (7%) | catalogued as CM001788, COSV60698790; called by muse, mutect2
- ROBO4 | c.936C>A p.G312= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as rs781111163, COSV100127794; called by muse, mutect2
- SEM1 | c.92G>A p.*31= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- SPINT2 | c.288G>T p.T96= | Silent (SNP) | VAF 39/494 reads (8%) | catalogued as COSV100007608; called by muse, mutect2
- TAF1L | c.3279C>T p.N1093= | Silent (SNP) | VAF 19/266 reads (7%) | called by muse, mutect2
- TLR4 | c.1260C>A p.G420= (on ENST00000355622 / NM_138554.5; = p.G380= on NM_003266.4) | Silent (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- TMEM241 | c.870C>T p.F290= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- TNFRSF1A | c.1251G>T p.T417= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs200473080; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNFRSF8 | c.543G>A p.P181= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs766705970, COSV55794471; called by muse, mutect2, varscan2
- TRBV29-1 | c.192A>T p.A64= | Silent (SNP) | VAF 42/450 reads (9%) | called by muse, mutect2
- TRPM5 | c.2457C>T p.I819= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs868160587; called by muse, mutect2, varscan2
- TSHB | c.336T>C p.Y112= | Silent (SNP) | VAF 42/512 reads (8%) | called by muse, mutect2
- UNC5C | c.453T>A p.G151= | Silent (SNP) | VAF 20/329 reads (6%) | catalogued as rs779904406; called by muse, mutect2
- VCAN | c.5487C>A p.A1829= | Silent (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- VEPH1 | c.849C>T p.F283= | Silent (SNP) | VAF 21/262 reads (8%) | catalogued as COSV100747546; called by muse, mutect2
- VPS35 | c.579C>G p.L193= | Silent (SNP) | VAF 31/316 reads (10%) | called by muse, mutect2, varscan2
- WDR90 | c.1980C>T p.P660= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs530269746, COSV53466142, COSV53473513; called by mutect2, varscan2
- XKR6 | c.1116G>C p.V372= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- ZNF611 | c.657A>T p.P219= | Silent (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- ZNF687 | c.3663G>T p.T1221= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- AC026271.3 | chr17:18701399 T>A | 5'Flank (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- ACTN1 | c.2521-61G>T | Intron (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.*78T>A | 3'UTR (SNP) | VAF 45/484 reads (9%) | called by muse, mutect2
- AL353804.7 | chrX:73851789 C>A | 3'Flank (SNP) | VAF 34/409 reads (8%) | called by muse, mutect2
- AP000769.3 | chr11:65504092 G>T | 5'Flank (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- BX119917.1 | n.76G>T | RNA (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- C1orf220 | n.360G>T | RNA (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- DDX60 | c.4533+43C>A | Intron (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- DNAH14 | c.3052-21512G>T | Intron (SNP) | VAF 52/407 reads (13%) | called by muse, mutect2, varscan2
- DPP6 | c.457+62A>T | Intron (SNP) | VAF 39/295 reads (13%) | called by muse, mutect2, varscan2
- ERLIN1 | c.*63A>G | 3'UTR (SNP) | VAF 29/344 reads (8%) | called by muse, mutect2
- FANCA | chr16:89816653 G>A | 5'Flank (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- FGF9 | c.*13C>A | 3'UTR (SNP) | VAF 27/396 reads (7%) | called by muse, mutect2
- HMBS | c.651+9G>C | Intron (SNP) | VAF 13/342 reads (4%) | called by muse, mutect2
- KIAA1755 | c.3+179C>T | Intron (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- LINC00917 | n.1468G>C | RNA (SNP) | VAF 15/301 reads (5%) | called by muse, mutect2
- MIR365B | chr17:31571295 G>A | 5'Flank (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- MTCH1 | c.-36G>A | 5'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs1039684781, COSV65321303; called by mutect2, varscan2
- NFKB1 | c.-2G>A | 5'UTR (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- NT5DC3 | c.-42C>G | 5'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- NXF3 | c.890+21C>A | Intron (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- PLAC9 | c.*120C>G | 3'UTR (SNP) | VAF 18/284 reads (6%) | called by muse, mutect2
- RNFT2 | c.*2488del | 3'UTR (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- SDC1 | c.66+1570G>A | Intron (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- SEM1 | c.*2G>C | 3'UTR (SNP) | VAF 36/257 reads (14%) | catalogued as COSV101303910; called by muse, mutect2, varscan2
- SMPD4BP | n.2521G>T | RNA (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- SYT14 | c.*799A>T | 3'UTR (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- TREML4 | c.-15C>G | 5'UTR (SNP) | VAF 8/88 reads (9%) | catalogued as rs1021612298; called by muse, mutect2
- UBBP4 | n.908C>G | RNA (SNP) | VAF 39/384 reads (10%) | called by muse, mutect2, varscan2
